Gene-level copy-number profile of tumor specimen TCGA-CV-A45U-01A from TCGA case TCGA-CV-A45U, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,746 days).
Specimen TCGA-CV-A45U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.57d8f56e-7b68-43e0-997f-6265c4c4c40a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A45U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50001a05-2d27-446b-ba8e-7ca8b53eee7d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4; copy number 2: 302; copy number 3: 11,909; copy number 4: 27,155; copy number 5: 10,154; copy number 6: 5,193; copy number 7: 3,099; copy number 8: 1,162; copy number 10: 367; copy number 11: 12; copy number 13: 14; copy number 14: 109; copy number 18: 52; copy number 19: 23; copy number 20: 1; copy number 21: 19; copy number 22: 168; copy number 25: 23; copy number 26: 22; copy number 28: 1; copy number 34: 6; copy number 39: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A45U-01A-12D-A24C-01): tumor purity 0.34, ploidy 5.27, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–21,995,301, 1 gene: CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 831 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–99,018,562, 77 genes, copy number 11–20 (within-gene range 8–20) (broad region; genes not listed).
- chr3:168,008,689–185,153,060, 302 genes, copy number 14–34 (broad region; genes not listed).
- chr3:191,199,241–191,591,097, 6 genes, copy number 28–34 (within-gene range 8–34): OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2.
- chr7:91,692,008–102,283,958, 283 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr11:69,294,151–73,142,318, 133 genes, copy number 10–39 (within-gene range 6–39) (broad region; genes not listed).
- chr12:95,858,928–96,485,442, 19 genes, copy number 21 (within-gene range 6–21): SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11.
- chr19:33,373,685–34,066,283, 11 genes, copy number 19: CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
